Somatic mutation profile of tumor specimen TCGA-B0-4821-01A (aliquot TCGA-B0-4821-01A-01D-1501-10) from TCGA case TCGA-B0-4821, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 68.5 years (25,013 days).
Specimen TCGA-B0-4821-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d8a4ce5-9708-4c0e-a2ba-a8a3c5a3a3fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-4821-11A (Solid Tissue Normal), aliquot TCGA-B0-4821-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b303f402-85b1-41e8-aceb-721cf356cbd5

The open-access MAF lists 75 somatic variants for this specimen: 55 protein-altering or splice-affecting, 20 silent.
By variant classification: Missense Mutation 47, Silent 20, Frame Shift Del 3, Nonsense Mutation 2, In Frame Del 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 42/242 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.6448C>T p.P2150S | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV101037628; called by muse, mutect2, varscan2
- ANGPTL1 | c.553C>G p.L185V | Missense Mutation (SNP) | VAF 59/184 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs767092542, COSV52365109; called by muse, mutect2, varscan2
- ANKRD44 | c.2021T>A p.L674Q | Missense Mutation (SNP) | VAF 60/218 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99985998; called by muse, mutect2, varscan2
- ANPEP | c.2486G>A p.R829Q | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.769); catalogued as rs375147227; called by muse, varscan2
- ASXL1 | c.840C>G p.F280L | Missense Mutation (SNP) | VAF 26/396 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs1334351668, COSV100041058; called by muse, mutect2
- C7orf57 | c.358G>C p.A120P | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as COSV100817325; called by muse, mutect2
- CBL | c.2485C>T p.R829W | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs761245258, COSV99877005; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDAN1 | c.3642G>C p.E1214D | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.074); catalogued as COSV99314793; called by muse, varscan2
- CEP290 | c.3973T>A p.L1325I | Missense Mutation (SNP) | VAF 360/1097 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.97); catalogued as COSV100469818; called by muse, mutect2, varscan2
- DDX60 | c.3536C>T p.S1179F | Missense Mutation (SNP) | VAF 196/758 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.086); catalogued as COSV101190650; called by muse, varscan2
- FANCB | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as COSV100146682; called by muse, mutect2, varscan2
- FARP1 | c.3065A>T p.E1022V | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100132065; called by muse, mutect2, varscan2
- FCN1 | c.603C>A p.S201R | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV100878967; called by muse, mutect2, varscan2
- FCN1 | c.602G>T p.S201I | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as COSV100878968; called by muse, mutect2, varscan2
- ITPRID1 | c.485T>C p.M162T | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1016412170, COSV100087480; called by muse, mutect2, varscan2
- KCNA6 | c.1376C>A p.S459Y | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99768971; called by muse, mutect2, varscan2
- KCNG4 | c.325C>A p.Q109K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV100377173; called by muse, mutect2, varscan2
- LGALS9C | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 20/107 reads (19%) | catalogued as rs766870750, COSV100055781; called by muse, mutect2, varscan2
- LMBRD2 | c.2005C>G p.P669A | Missense Mutation (SNP) | VAF 33/550 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.085); catalogued as COSV99683252; called by muse, mutect2
- MAGEE1 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782397816, COSV100819528, COSV63910611; called by muse, mutect2, varscan2
- MAN2C1 | c.2218G>C p.D740H | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144613264, COSV51229027; called by muse, mutect2, varscan2
- MAP3K12 | c.1463A>G p.K488R | Missense Mutation (SNP) | VAF 113/304 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.194); catalogued as COSV99913547; called by muse, mutect2, varscan2
- MCOLN2 | c.1213G>T p.V405L | Missense Mutation (SNP) | VAF 88/239 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.12); catalogued as rs879264635, COSV99394249; called by muse, mutect2, varscan2
- MYH4 | c.242A>T p.N81I | Missense Mutation (SNP) | VAF 54/660 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99702203; called by muse, mutect2
- MYO5B | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 92/394 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99546214; called by muse, mutect2, varscan2
- MYO9B | c.2885T>A p.L962Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as COSV101261933; called by muse, varscan2
- NR2F2 | c.379C>T p.H127Y | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101241170; called by muse, mutect2, varscan2
- OPTC | c.102G>A p.M34I | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100557951; called by muse, mutect2, varscan2
- POLD2 | c.1231G>T p.G411C | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99789105; called by muse, mutect2, varscan2
- POLH | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV64780559; called by muse, mutect2, varscan2
- PTCHD4 | c.898T>C p.F300L | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV100261610; called by muse, mutect2, varscan2
- PXDNL | c.2090C>A p.P697Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as rs374573903, COSV62482449; called by muse, mutect2, varscan2
- RPL10L | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs372260544; called by mutect2, varscan2
- SHROOM2 | c.2291C>T p.S764L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1442536064, COSV101098480; called by muse, mutect2, varscan2
- SHROOM4 | c.2456G>A p.R819K | Missense Mutation (SNP) | VAF 115/388 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99174591; called by muse, mutect2, varscan2
- SLC22A18 | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.247); catalogued as COSV100388972; called by muse, mutect2
- SUSD1 | c.1600G>T p.E534* | Nonsense Mutation (SNP) | VAF 86/238 reads (36%) | catalogued as COSV100813494; called by muse, varscan2
- TACC2 | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs1380677810, COSV100551279; called by muse, mutect2, varscan2
- TMEM222 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.795); catalogued as COSV100929996; called by muse, mutect2, varscan2
- TRPM6 | c.801G>C p.R267S | Missense Mutation (SNP) | VAF 91/228 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV100666955; called by muse, mutect2, varscan2
- USP34 | c.4691A>G p.K1564R | Missense Mutation (SNP) | VAF 24/395 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.899); catalogued as COSV101277205; called by muse, mutect2
- ZC3HC1 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV100316042; called by muse, mutect2, varscan2
- ZNF454 | c.553A>G p.K185E | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100195379; called by muse, mutect2, varscan2
- ADAM33 | c.2072G>T p.S691I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAM33 | c.2071A>T p.S691C | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AMPD1 | c.1917del p.L640Cfs*4 | Frame Shift Del (DEL) | VAF 57/288 reads (20%) | called by mutect2, pindel, varscan2
- GALNT17 | c.629_630insAG p.Y211Afs*6 | Frame Shift Ins (INS) | VAF 53/170 reads (31%) | called by mutect2, pindel, varscan2
- LNPK | c.655_660del p.N219_V220del | In Frame Del (DEL) | VAF 43/219 reads (20%) | called by mutect2, pindel, varscan2
- NRDC | c.2378_2379del p.F793* | Frame Shift Del (DEL) | VAF 35/263 reads (13%) | called by mutect2, pindel, varscan2
- PLA2G4F | c.653T>C p.L218P | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.276); called by muse, mutect2
- PRAMEF8 | c.95C>A p.P32H | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRAMEF8 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RHBDF1 | c.1940_1941del p.P647Rfs*4 | Frame Shift Del (DEL) | VAF 17/73 reads (23%) | called by mutect2, pindel, varscan2
- SETD2 | c.6109_6109+1dup p.X2037_splice | Splice Site (INS) | VAF 193/559 reads (35%) | called by mutect2, pindel, varscan2
- AGBL1 | c.1758G>A p.L586= | Silent (SNP) | VAF 91/382 reads (24%) | catalogued as COSV101224203; called by muse, varscan2
- CELSR1 | c.5184G>C p.L1728= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV99420004; called by mutect2, varscan2
- CEP350 | c.8133T>A p.A2711= | Silent (SNP) | VAF 34/145 reads (23%) | catalogued as COSV100855216; called by muse, mutect2, varscan2
- DDX28 | c.1449C>T p.H483= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs759259392, COSV100193150; called by muse, mutect2, varscan2
- GABRG2 | c.1461C>A p.I487= (on ENST00000361925 / NM_001375343.1; = p.I447= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/630 reads (10%) | catalogued as COSV100729623; called by muse, mutect2
- GAD2 | c.1152G>A p.V384= | Silent (SNP) | VAF 109/364 reads (30%) | catalogued as COSV99394021; called by muse, mutect2, varscan2
- GRM3 | c.1401C>T p.N467= | Silent (SNP) | VAF 56/164 reads (34%) | catalogued as rs765776830, COSV64469657; called by muse, mutect2, varscan2
- HMGCL | c.531A>G p.E177= | Silent (SNP) | VAF 48/135 reads (36%) | catalogued as COSV99354104; called by muse, mutect2, varscan2
- IFT52 | c.999C>T p.T333= | Silent (SNP) | VAF 28/143 reads (20%) | catalogued as COSV100887675, COSV65976119; called by muse, mutect2, varscan2
- IMPG1 | c.1170C>T p.D390= | Silent (SNP) | VAF 50/192 reads (26%) | catalogued as rs1228477654, COSV100886661; called by muse, mutect2, varscan2
- KCNG4 | c.324C>T p.S108= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100377174; called by muse, mutect2, varscan2
- KIAA1217 | c.5493T>C p.T1831= | Silent (SNP) | VAF 106/405 reads (26%) | catalogued as COSV100287272; called by muse, mutect2, varscan2
- MAGEB18 | c.189G>A p.A63= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs1396873546, COSV100305628; called by muse, mutect2, varscan2
- MSN | c.702A>G p.L234= | Silent (SNP) | VAF 147/557 reads (26%) | catalogued as COSV100814304; called by muse, mutect2, varscan2
- OR5AS1 | c.912A>T p.L304= | Silent (SNP) | VAF 41/176 reads (23%) | catalogued as COSV100546377; called by muse, mutect2, varscan2
- PLCL1 | c.1044C>T p.I348= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as COSV101407283; called by muse, mutect2, varscan2
- RAPGEF2 | c.301C>T p.L101= | Silent (SNP) | VAF 45/298 reads (15%) | catalogued as COSV100031634, COSV52432617; called by muse, mutect2, varscan2
- TNR | c.2259C>T p.S753= | Silent (SNP) | VAF 28/272 reads (10%) | catalogued as rs549333643, COSV54901010; called by muse, mutect2
- TOPBP1 | c.3255G>A p.V1085= | Silent (SNP) | VAF 143/467 reads (31%) | catalogued as COSV53441820; called by muse, mutect2, varscan2
- TRPM7 | c.4404T>G p.S1468= | Silent (SNP) | VAF 87/309 reads (28%) | catalogued as COSV100540315; called by muse, mutect2, varscan2
